CCDI case PBCMZC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/252b7695-a4e8-4796-b8f1-265451c737a8

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 8.7 years (3,180 days).

Biospecimens (3 samples)
- Sample 0DVVIC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVVL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVVMC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
